CCDI case PBBKPN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ebc0ef3c-9dce-428b-9b1a-8fe6e8a56c42

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebrum; Age at diagnosis: 3.7 years (1,358 days).

Biospecimens (3 samples)
- Sample 0DB2AQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB2AW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB2B8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
